Somatic mutation profile of tumor specimen TCGA-75-6207-01A (aliquot TCGA-75-6207-01A-11D-1753-08) from TCGA case TCGA-75-6207, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA.
Specimen TCGA-75-6207-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10fd9e5a-9730-4ca1-a470-35eba9903ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-6207-10A (Blood Derived Normal), aliquot TCGA-75-6207-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9e60d1f-e1a5-4afd-bb85-8d7586646e45

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 38, Silent 14, Nonsense Mutation 6, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 16/66 reads (24%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFF4 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54791352; called by muse, varscan2
- ARID1A | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 88/180 reads (49%) | catalogued as COSV61371604, COSV61372723; called by muse, mutect2, varscan2
- BAIAP2L1 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50054597; called by muse, mutect2, varscan2
- BMPR1B | c.1405C>A p.L469I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.804); catalogued as COSV52774669; called by muse, mutect2, varscan2
- DCAF13 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV52570416, COSV99885274; called by muse, mutect2, varscan2
- DEUP1 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV53209533; called by muse, mutect2, varscan2
- DISP1 | c.3305T>G p.V1102G | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52654470; called by muse, mutect2, varscan2
- DSE | c.1783G>T p.E595* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV59061711; called by muse, varscan2
- F5 | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63120286; called by muse, mutect2
- FAM124A | c.1499C>A p.A500D (on ENST00000322475 / NM_001242312.2; = p.A536D on NM_145019.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV54474308; called by muse, mutect2, varscan2
- GABRA1 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.08); catalogued as COSV50098708; called by muse, mutect2
- GP2 | c.1441C>A p.Q481K (on ENST00000381362 / NM_001007240.3; = p.Q478K on NM_001502.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV56891968, COSV56896862; called by muse, mutect2, varscan2
- HMCN1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs981918593, COSV54876195; called by muse, mutect2, varscan2
- IGHM | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.205); catalogued as rs373687984; called by muse, mutect2
- IRS4 | c.3506C>G p.A1169G | Missense Mutation (SNP) | VAF 85/102 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV64532579; called by muse, mutect2, varscan2
- KHDC4 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV64164516; called by muse, mutect2, varscan2
- KIAA2026 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.192); catalogued as COSV52388091; called by muse, mutect2, varscan2
- KRTAP9-8 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV54200432; called by muse, mutect2, varscan2
- LRFN5 | c.174G>T p.L58F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53242624; called by muse, mutect2, varscan2
- MAN1C1 | c.582G>C p.M194I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV56041531; called by muse, mutect2, varscan2
- MGAT4C | c.788T>A p.L263H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153539, COSV59829738; called by muse, mutect2, varscan2
- MTMR1 | c.1001C>A p.S334* | Nonsense Mutation (SNP) | VAF 41/54 reads (76%) | catalogued as COSV64892189; called by muse, mutect2, varscan2
- NPBWR1 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100488131; called by muse, mutect2, varscan2
- OR2S2 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100558503; called by muse, mutect2, varscan2
- OR51F1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58578759; called by muse, mutect2, varscan2
- PCLO | c.13129G>A p.A4377T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV61615270; called by muse, mutect2, varscan2
- PLEKHH1 | c.2281C>T p.H761Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV100232508, COSV61280064; called by muse, mutect2, varscan2
- PREX2 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55750128, COSV55781439; called by muse, mutect2, varscan2
- PRRC2C | c.4237C>T p.R1413* (on ENST00000367742; = p.R1411* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV58900794; called by muse, mutect2, varscan2
- RGS2 | c.6A>T p.Q2H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV52458642; called by muse, mutect2
- RPE65 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52013066; called by muse, mutect2, varscan2
- SHPRH | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV51604574; called by muse, mutect2, varscan2
- SLITRK3 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as rs1448333933, COSV53845534; called by muse, mutect2, varscan2
- SNTA1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148604302; called by muse, mutect2, varscan2
- SPATA7 | c.1793A>C p.D598A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV50415897; called by muse, mutect2, varscan2
- SSU72P8 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV66361010; called by muse, mutect2, varscan2
- TNS2 | c.3337G>C p.D1113H (on ENST00000314250 / NM_170754.4; = p.D1123H on NM_015319.2) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56852251; called by muse, mutect2, varscan2
- UBAP2 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62545122, COSV62548234; called by muse, mutect2, varscan2
- WBP11 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53761677; called by muse, mutect2, varscan2
- WTAP | c.350T>A p.I117N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61609808; called by muse, mutect2, varscan2
- XIRP2 | c.1709G>C p.R570T (on ENST00000628543; = p.R745T on NM_152381.6) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV54681924; called by muse, mutect2, varscan2
- ZNF419 | c.1525A>T p.M509L | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.145); catalogued as COSV55657390; called by muse, mutect2, varscan2
- ZNF676 | c.1418G>C p.R473T (on ENST00000650058; = p.R441T on NM_001001411.3) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as rs764369632, COSV101236165, COSV68092102, COSV68092115; called by muse, mutect2, varscan2
- CKMT2 | c.429_430dup p.D144Gfs*32 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- FAM220A | c.298_337del p.P100Vfs*92 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel
- SLC34A2 | c.1687_1689del p.V563del | In Frame Del (DEL) | VAF 35/94 reads (37%) | called by pindel, varscan2
- AHNAK2 | c.7698G>T p.L2566= | Silent (SNP) | VAF 83/255 reads (33%) | catalogued as COSV60907382; called by muse, mutect2, varscan2
- ALK | c.2436T>C p.H812= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV66556929; called by muse, mutect2
- CYP11B2 | c.120C>A p.A40= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV59994386, COSV59995441; called by muse, mutect2, varscan2
- DLGAP2 | c.768C>A p.G256= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV70093831; called by muse, mutect2, varscan2
- HLA-DMA | c.297A>G p.L99= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as COSV66385397; called by muse, mutect2, varscan2
- IGSF9 | c.1881G>A p.P627= (on ENST00000368094 / NM_001135050.2; = p.P611= on NM_020789.4) | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs1439793751, COSV63638747; called by muse, mutect2, varscan2
- JPH2 | c.348C>T p.D116= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs778483216, COSV60696339; called by muse, mutect2, varscan2
- KCNB2 | c.1602T>C p.H534= | Silent (SNP) | VAF 5/115 reads (4%) | catalogued as COSV73048844; called by muse, mutect2
- NAP1L2 | c.1140C>T p.T380= | Silent (SNP) | VAF 48/63 reads (76%) | catalogued as COSV65172145; called by muse, mutect2, varscan2
- PCDHB4 | c.909A>G p.K303= | Silent (SNP) | VAF 80/230 reads (35%) | catalogued as COSV52019466; called by muse, mutect2, varscan2
- PDE4DIP | c.276G>A p.T92= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs782702075; called by muse, mutect2, varscan2
- RFPL3 | c.157C>T p.L53= (on ENST00000249007 / NM_001098535.1; = p.L24= on NM_006604.2) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs1569430674, COSV50748506; called by muse, mutect2, varscan2
- RLN1 | c.321A>T p.P107= | Silent (SNP) | VAF 30/454 reads (7%) | catalogued as COSV56346104; called by muse, mutect2
- SNAI2 | c.453C>T p.C151= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV50078629, COSV50080015; called by muse, mutect2, varscan2
